Somatic mutation profile of tumor specimen TARGET-30-PAPSMC-01A (aliquot TARGET-30-PAPSMC-01A-01W) from TARGET case TARGET-30-PAPSMC, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Medulla of adrenal gland; Age at diagnosis: 3.7 years (1,337 days).
Specimen TARGET-30-PAPSMC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 01afc769-ceb9-4a03-8060-60f6d45cd4e1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAPSMC-10A (Blood Derived Normal), aliquot TARGET-30-PAPSMC-10A-01W; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c43ae92d-bc51-469f-92aa-1eeb738ddd91

The open-access MAF lists 8 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 7, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CLEC4C | c.472C>A p.Q158K | Missense Mutation (SNP) | VAF 14/292 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.248); catalogued as COSV63582207; called by muse, mutect2
- F11R | c.68C>T p.S23F | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV57038499; called by muse, mutect2
- NOP9 | c.889G>A p.A297T | Missense Mutation (SNP) | VAF 14/168 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.027); catalogued as rs768126506, COSV51864380, COSV99350910; called by muse, mutect2
- PITPNC1 | c.166C>A p.Q56K | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV55456518; called by muse, mutect2, varscan2
- SSPN | c.545C>T p.T182M | Missense Mutation (SNP) | VAF 22/338 reads (7%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.781); catalogued as rs200190223; called by muse, mutect2
- EPHA4 | c.2637C>A p.D879E | Missense Mutation (SNP) | VAF 18/694 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); called by muse, mutect2
- SULT1C2 | c.134G>T p.C45F | Missense Mutation (SNP) | VAF 17/234 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); called by muse, mutect2
- PIGG | c.1374C>T p.R458= (on ENST00000453061 / NM_001127178.3; = p.R450= on NM_017733.4) | Silent (SNP) | VAF 8/116 reads (7%) | called by muse, mutect2
